Somatic mutation profile of tumor specimen MMRF_2366_1_BM_CD138pos (aliquot MMRF_2366_1_BM_CD138pos_T2_KHS5U_K14035) from MMRF case MMRF_2366, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.7 years (27,633 days).
Specimen MMRF_2366_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ca3807e-b787-47af-9724-a754a73c1845.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2366_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2366_1_PB_Whole_C1_KHS5U_K14034; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fee824fc-a4b1-4264-8181-0fe16e84a330

The open-access MAF lists 97 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 33, Intron 7, Silent 7, 3'Flank 4, 5'Flank 2, RNA 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 40/78 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTF3 | c.202-6C>T | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as rs773584902; called by muse, mutect2
- CACNA1A | c.1825A>G p.N609D | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1476877900; called by muse, mutect2
- CCDC168 | c.11519C>T p.T3840M | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs370748972; called by muse, mutect2, varscan2
- CDH23 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 127/257 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs531513127, COSV56452048; called by muse, mutect2, varscan2
- DCC | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 8/166 reads (5%) | catalogued as COSV59100342; called by muse, mutect2
- DISP1 | c.3638C>T p.T1213I | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.11); catalogued as rs1445260660; called by muse, mutect2
- DYNC2LI1 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1474245852; called by muse, mutect2, varscan2
- GRIA4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 141/610 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV56881305; called by muse, mutect2, varscan2
- KALRN | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768341806, COSV53755646; called by muse, mutect2
- KIAA1549L | c.4153G>A p.A1385T (on ENST00000321505; = p.A1682T on NM_012194.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV100382765; called by muse, mutect2, varscan2
- MMP1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747080313, COSV59510485; called by muse, mutect2, varscan2
- MRTFB | c.2711A>G p.N904S (on ENST00000571589 / NM_001365412.2; = p.N854S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs114283484; called by muse, mutect2, varscan2
- OR10G7 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV57866725; called by muse, mutect2
- PABPC3 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55806818; called by muse, mutect2, varscan2
- TLR4 | c.243G>T p.Q81H (on ENST00000355622 / NM_138554.5; = p.Q41H on NM_003266.4) | Missense Mutation (SNP) | VAF 495/716 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV100790625; called by muse, mutect2, varscan2
- TOGARAM2 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs756772607, COSV65420229; called by muse, mutect2, varscan2
- ABCC9 | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADH1A | c.1088T>G p.L363R | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL1 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANKRD18B | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- BAIAP3 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRM3 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSF1R | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DDIAS | c.1485C>G p.F495L | Missense Mutation (SNP) | VAF 98/644 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX46 | c.1719G>T p.R573S | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- EVI5L | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHD3-9 | c.2T>G p.V1G | Missense Mutation (SNP) | VAF 26/26 reads (100%) | called by muse, mutect2, varscan2
- KIF21A | c.682_695del p.A228Sfs*14 | Frame Shift Del (DEL) | VAF 55/291 reads (19%) | called by mutect2, pindel, varscan2
- MBD4 | c.875A>C p.D292A | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OVOL2 | c.528A>T p.K176N | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH7 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KA6 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- RREB1 | c.1188_1189insT p.K397* | Frame Shift Ins (INS) | VAF 86/226 reads (38%) | called by mutect2, pindel, varscan2
- TTN | c.93914G>A p.R31305K (on ENST00000591111; = p.R23881K on NM_003319.4) | Missense Mutation (SNP) | VAF 49/191 reads (26%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB41 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ZSCAN23 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- AP2B1 | c.1455T>C p.L485= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1560G>A p.S520= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1362509873, COSV99984481; called by muse, mutect2, varscan2
- DDIAS | c.648C>T p.S216= | Silent (SNP) | VAF 175/1125 reads (16%) | called by muse, mutect2, varscan2
- HIVEP1 | c.3322C>T p.L1108= | Silent (SNP) | VAF 31/311 reads (10%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.339G>A p.V113= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- PRMT9 | c.114C>T p.V38= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs200596602; called by muse, mutect2, varscan2
- SSBP4 | c.72C>T p.Y24= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs377735423; called by muse, mutect2, varscan2
- AC073140.1 | n.99A>C | RNA (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- AC124947.1 | n.332G>T | RNA (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- ADAMTS5 | c.*675T>C | 3'UTR (SNP) | VAF 91/91 reads (100%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+1751T>G | Intron (SNP) | VAF 5/132 reads (4%) | called by muse, mutect2
- AKAP9 | chr7:91940898 C>T | 5'Flank (SNP) | VAF 6/70 reads (9%) | catalogued as rs1453218272; called by muse, mutect2
- ALS2 | c.*280dup | 3'UTR (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- ANGPT1 | c.*1567A>C | 3'UTR (SNP) | VAF 71/199 reads (36%) | catalogued as rs1181384612; called by muse, mutect2, varscan2
- ARHGAP24 | c.268+505C>T | Intron (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- ARHGAP42 | c.*3508A>G | 3'UTR (SNP) | VAF 23/232 reads (10%) | catalogued as rs866087029; called by muse, mutect2, varscan2
- ATRNL1 | c.*4030A>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021411 G>C | 5'Flank (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55846921, COSV55847077; called by muse, mutect2, varscan2
- C1QL1 | c.*370C>T | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2
- C2orf49 | c.*1224T>G | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- C9orf50 | c.880+33C>G | Intron (SNP) | VAF 51/219 reads (23%) | called by muse, mutect2, varscan2
- CAND1 | c.*184G>A | 3'UTR (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- CDK2 | c.*1011C>T | 3'UTR (SNP) | VAF 6/88 reads (7%) | catalogued as rs1334161636; called by muse, mutect2
- CIR1 | c.485-6472_485-6469del | Intron (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- CMTR2 | c.*501C>T | 3'UTR (SNP) | VAF 13/109 reads (12%) | catalogued as rs1051434835; called by muse, mutect2, varscan2
- COLGALT2 | c.1137-897G>T | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- CRTAM | c.*200del | 3'UTR (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- DNASE1 | chr16:3662686 G>A | 3'Flank (SNP) | VAF 44/219 reads (20%) | called by muse, mutect2, varscan2
- ELK4 | c.*6339T>A | 3'UTR (SNP) | VAF 19/109 reads (17%) | catalogued as rs1216239990; called by muse, mutect2, varscan2
- ENGASE | c.*234T>G | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- FAM169A | c.*2131A>C | 3'UTR (SNP) | VAF 7/18 reads (39%) | catalogued as rs941940977; called by muse, mutect2, varscan2
- FAM221B | c.*1075G>A | 3'UTR (SNP) | VAF 56/385 reads (15%) | called by muse, mutect2, varscan2
- FFAR3 | c.*404G>T | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, varscan2
- FOXO3B | c.*966T>C | 3'UTR (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- GSTZ1 | c.217-73G>A | Intron (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+1797T>C | Intron (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- HNRNPH2 | c.*115T>C | 3'UTR (SNP) | VAF 31/288 reads (11%) | catalogued as rs1161308459; called by muse, mutect2, varscan2
- ITGA8 | c.*3191_*3196del | 3'UTR (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- KCNK12 | c.*7730C>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs943171696, COSV59946159; called by muse, varscan2
- KCTD9 | c.*3A>G | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- LMO4 | chr1:87346029 T>C | 3'Flank (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- NF2 | c.*3053C>T | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as rs1165269447; called by muse, mutect2, varscan2
- OSBPL6 | c.*3771A>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PENK | chr8:56436928 G>A | 3'Flank (SNP) | VAF 80/251 reads (32%) | catalogued as rs1431535572; called by muse, mutect2, varscan2
- PLPBP | c.*1288T>G | 3'UTR (SNP) | VAF 18/134 reads (13%) | called by muse, varscan2
- PSAPL1 | c.*1765G>A | 3'UTR (SNP) | VAF 87/92 reads (95%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82979740 A>G | 3'Flank (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- RAMAC | c.*542T>G | 3'UTR (SNP) | VAF 136/380 reads (36%) | called by muse, mutect2, varscan2
- RIC8B | c.*280C>T | 3'UTR (SNP) | VAF 11/59 reads (19%) | catalogued as rs367631786; called by muse, mutect2, varscan2
- SLC13A1 | c.*1511G>T | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- SLIT3 | c.*2923A>G | 3'UTR (SNP) | VAF 57/302 reads (19%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*3499C>T | 3'UTR (SNP) | VAF 97/290 reads (33%) | catalogued as rs989362436; called by muse, mutect2, varscan2
- SYT10 | c.*1884G>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- TMEM169 | c.*1500G>A | 3'UTR (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- TSPAN32 | c.*2G>A | 3'UTR (SNP) | VAF 34/104 reads (33%) | catalogued as rs372687754; called by muse, mutect2, varscan2
- TSSK1B | c.*458G>C | 3'UTR (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1235T>C | 3'UTR (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- UBXN10 | c.*2587C>T | 3'UTR (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- WNT2B | c.*3824C>T | 3'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- ZNF746 | c.*509C>T | 3'UTR (SNP) | VAF 34/105 reads (32%) | catalogued as rs1563246255; called by muse, mutect2, varscan2
